Somatic mutation profile of tumor specimen MP2PRT-PASNAY-TMP1-A (aliquot MP2PRT-PASNAY-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASNAY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,395 days).
Specimen MP2PRT-PASNAY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d7e86d5-81be-4bb8-af57-04048ff3a6d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNAY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNAY-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29fc3d94-acca-4945-a698-ffd6ecd9fabe

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Frame Shift Ins 1, 5'Flank 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASZ1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 132/343 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52911072, COSV52912082, COSV52914975; called by muse, mutect2, varscan2
- BDNF | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 45/396 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs757598331; called by muse, mutect2, varscan2
- COL4A6 | c.3583G>A p.G1195S | Missense Mutation (SNP) | VAF 88/129 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779915691, COSV57873378; called by muse, mutect2, varscan2
- POTEE | c.2060A>G p.N687S | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs1378704143; called by muse, mutect2
- XRRA1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 102/296 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371595882; called by muse, mutect2, varscan2
- GTF3C1 | c.1913A>G p.Q638R | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- IGHV5-51 | chr14:106578742 TGTCTCGCAC>CCGGGTG | Missense Mutation (DEL) | VAF 71/243 reads (29%) | called by pindel, varscan2*
- IGKV1D-16 | c.351delinsCCGGGC p.*118Rfs*? | Frame Shift Ins (INS) | VAF 61/205 reads (30%) | called by pindel, varscan2*
- MGA | c.1695_1707delinsTCGGGG p.L566Rfs*32 | Frame Shift Del (DEL) | VAF 79/316 reads (25%) | called by pindel, varscan2*
- OR5F1 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP2CB | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 157/421 reads (37%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANXA9 | c.534G>T p.L178= | Silent (SNP) | VAF 97/272 reads (36%) | called by muse, mutect2, varscan2
- ARMH4 | c.928T>C p.L310= | Silent (SNP) | VAF 113/296 reads (38%) | catalogued as rs771577684; called by muse, mutect2, varscan2
- COL6A3 | c.7695G>A p.A2565= | Silent (SNP) | VAF 98/300 reads (33%) | catalogued as rs200456255, COSV55092747; called by muse, mutect2, varscan2
- PABPC4 | c.714C>T p.Y238= | Silent (SNP) | VAF 103/297 reads (35%) | catalogued as rs978254136, COSV63293634; called by muse, mutect2, varscan2
- WTIP | c.1101C>A p.I367= | Silent (SNP) | VAF 31/365 reads (8%) | called by muse, mutect2
- IGHV1-58 | chr14:106627248 ins CCTTCCC | 5'Flank (INS) | VAF 14/74 reads (19%) | called by pindel, varscan2
- IGHV4-61 | chr14:106639118 ins CCTTCCC | 3'Flank (INS) | VAF 28/159 reads (18%) | called by pindel, varscan2
